Surgical pathology report (de-identified scan), TCGA case TCGA-HC-7749, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-HC-7749-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

*** ADDENDUM REPORT ***

ADDENDUM REPORT:

At the request [REDACTED] case is reviewed for clarification of the margin in specimen A. The tumor in specimen A (separately submitted as right lateral margin) is present within fibroconnective tissue, but does not involve the fibroadipose tissue and is therefore interpreted as clear of the true surgical margin in this section. Additionally, a single gland representing prostatic adenocarcinoma is present within loose fibroconnective tissue within the fat plain in the main resection. Therefore, according to The [REDACTED] [REDACTED] this represents focal extraprostatic extension. The staging is therefore changed to a pT3.

These findings were discussed [REDACTED]

Addendum Report Issued By: [REDACTED]

DIAGNOSIS

DIAGNOSIS:

A. Right lateral margin; excision:

Prostatic adenocarcinoma, 4 mm in greatest dimension.

B. Prostate, vas deferens, seminal vesicals; radical prostatectomy:

Tumor Characteristics:

1. Histologic type: Prostatic adenocarcinoma.
2. Prostate size: 6.0 x 4.2 x 3.5 cm, 41.0 gm.
3. Tumor quantitation: Tumor occupies approximately 10-20% of the prostate volume.
4. Gleason grade:
- a. Primary pattern: 4/5.
- b. Secondary pattern: 3/5.
- c. Tertiary pattern: 5/5.
- d. Total Gleason score: 7/10.
5. Extraprostatic extension: Not identified.
6. Seminal vesicle involvement: Not identified.
7. Lymphovascular space invasion: Not identified.
8. High grade PIN: Present.
9. Treatment effect: Not identified.

Surgical Margin Status:

1. Prostatic adenocarcinoma extends to the right lateral margin in the main resection, see specimen A for additionally submitted right lateral margin.

Lymph Node Status:

1. Total number of lymph nodes examined:
- a. Five.
- b. Four separately submitted lymph nodes, see specimen C.
- c. One lymph node present within soft tissue adjacent to the main resection specimen.
2. Total number of lymph nodes containing metastatic carcinoma: Zero (0/5).

Other:

1. Perineural invasion present.
2. pTNM stage: pT2cN0.

C. Lymph nodes; excision:

No metastatic carcinoma identified in four lymph nodes (0/4).

[page 2 of 2]
CLINICAL INFORMATION

CLINICAL HISTORY:

Preoperative Diagnosis: ■ year old male with prostate cancer.

Postoperative Diagnosis:

Symptoms/Radiologic Findings:

SPECIMENS:

- A. Right lateral margin.
- B. Prostate vas deferens seminal vesical.
- C. Lymph nodes.

SPECIMEN DATA

GROSS DESCRIPTION:

The specimen is received in three containers labeled the patient's name

A. Container A is additionally labeled right lateral margin and contains a 1.6 x 0.9 x 0.7 cm. pink-tan irregular soft tissue bearing a white clip. The specimen is inked, bisected to reveal a yellow-tan fibrofatty cut surface. The specimen is entirely submitted in cassette A labeled

B. Container B is additionally labeled prostate vas deferens seminal vesical and contains a 40.9 gram, 6.0 x 4.2 x 3.5 cm. prostate received with attached bilateral adnexa having overall dimensions of 5.5 x 3.3 x 0.5 cm. The capsule is pink-tan and shaggy. The specimen is inked as follows: right side black; left side yellow. The base and apical margins are coned and serially sectioned. The remainder of the gland is serially sectioned from apex to base to reveal an ill defined yellow-tan lesion 3.5 cm. in greatest dimension. This lesion involves the right anterior and posterior quadrants and approaches to within 0.1 cm. of the inked capsule. Additionally, this lesion is present at the right prostate/seminal vesical junction. The remainder of the cut surface is pink-tan focally cystic and features diffuse periurethral nodularity.

Also received in the same container is a 3.5 x 2.4 x 1.0 cm. aggregate of yellow-tan fibrofatty soft tissue. On palpation, a 2.5 cm. nodule is identified consistent with possible lymph node. Representative sections are submitted in cassettes B1-19 labeled ■ designated as follows: 1—right prostate/seminal vesical junction; 2—left prostate/seminal vesical junction; 3 and 4—apical margin, perpendicular; 5 and 6—base margin, perpendicular; 7-9 right anterior, apex to base; 10-12 right posterior, apex to base; 13 through 15—left anterior, apex to base; 16 through 18—left posterior, apex to base; B19—one whole possible bisected lymph node.

Additionally, a yellow, green and blue cassette are submitted for Genomics research each labeled ■

C. Container C is additionally labeled lymph nodes and contains a 5.5 x 4.4 x 2.0 cm. aggregate of yellow-tan fibrofatty soft tissue. On palpation, four firm fatty possible lymph nodes are identified ranging from 0.9 up to 2.5 cm. in greatest dimension. They are entirely submitted in cassettes C1-4 labeled ■ designated as follows: C1—one whole possible lymph node; C2 through 4—one whole possible bisected lymph node in each cassette.

Source: NCI Genomic Data Commons file 2ab0feb3-207d-46fd-ac19-ec1085714995 (TCGA-HC-7749.35E33CB7-77A7-4D02-B4EC-9374423027C0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).